Somatic mutation profile of tumor specimen MMRF_2152_1_BM_CD138pos (aliquot MMRF_2152_1_BM_CD138pos_T1_KHS5U_L08695) from MMRF case MMRF_2152, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.1 years (19,409 days).
Specimen MMRF_2152_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11eb7162-1a50-4cec-892c-93d896bb2672.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2152_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2152_1_PB_Whole_C2_KHS5U_L08694; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db3ce9ad-382c-46c0-b0e6-1c58b43d3777

The open-access MAF lists 191 somatic variants for this specimen: 88 protein-altering or splice-affecting, 19 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, 3'UTR 45, Intron 19, Silent 19, 5'UTR 8, 3'Flank 6, Nonsense Mutation 5, Frame Shift Del 5, RNA 4, Frame Shift Ins 3, 5'Flank 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 88/176 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF5 | c.2616_2617del p.G874Sfs*30 | Frame Shift Del (DEL) | VAF 30/288 reads (10%) | catalogued as rs763308825; called by mutect2, varscan2
- ATG9B | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 80/128 reads (63%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs773999613; called by muse, mutect2, varscan2
- BTNL8 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 189/202 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1224889478, COSV51456891; called by muse, mutect2, varscan2
- CAMK2B | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51661619; called by muse, mutect2, varscan2
- CCDC71 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs752522691, COSV58909890; called by muse, mutect2, varscan2
- DAB2IP | c.805C>T p.R269C (on ENST00000408936; = p.R241C on NM_032552.3) | Missense Mutation (SNP) | VAF 156/324 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs759742711, COSV52258888; called by muse, mutect2, varscan2
- DACT2 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as rs1278280445; called by muse, mutect2, varscan2
- DYNC2LI1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); catalogued as rs1200727370; called by muse, mutect2
- FSIP2 | c.11944G>T p.E3982* | Nonsense Mutation (SNP) | VAF 59/126 reads (47%) | catalogued as COSV58103742; called by muse, mutect2, varscan2
- GRM8 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 111/638 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); catalogued as rs569817460, COSV58846803; called by muse, mutect2, varscan2
- IGLV3-1 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.445); catalogued as rs374050608; called by muse, varscan2
- IGLV3-1 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 155/242 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs559078152; called by muse, varscan2
- KIFC3 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1000625098, COSV65549277; called by muse, mutect2, varscan2
- MIOX | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 119/400 reads (30%) | catalogued as rs757798383, COSV53314958; called by muse, mutect2, varscan2
- MYO3A | c.3817T>C p.W1273R | Missense Mutation (SNP) | VAF 94/315 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1400890589, COSV99778916; called by muse, mutect2, varscan2
- NR1D2 | c.1730T>C p.V577A | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs200401146; called by muse, mutect2, varscan2
- RASGRF2 | c.3646G>C p.D1216H | Missense Mutation (SNP) | VAF 166/570 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV104370422; called by muse, mutect2, varscan2
- SCUBE1 | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1185254051; called by muse, mutect2, varscan2
- SPINDOC | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV99588750; called by muse, mutect2, varscan2
- STK32C | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 156/174 reads (90%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.955); catalogued as rs908109999, COSV53838087; called by muse, mutect2, varscan2
- WDSUB1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs141991034; called by muse, mutect2, varscan2
- YTHDF2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs746319944, COSV65724104; called by muse, mutect2, varscan2
- ZNF662 | c.470T>A p.V157E | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs931400413; called by muse, mutect2, varscan2
- AKAP6 | c.6912A>T p.E2304D | Missense Mutation (SNP) | VAF 167/345 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALG13 | c.2195T>A p.I732N | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ANKK1 | c.1823T>C p.I608T | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ANKRD12 | c.507T>G p.S169R | Missense Mutation (SNP) | VAF 163/574 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ARHGAP20 | c.3568G>T p.D1190Y | Missense Mutation (SNP) | VAF 119/440 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ATP5F1C | c.485C>G p.T162S | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- BTAF1 | c.2605C>T p.Q869* | Nonsense Mutation (SNP) | VAF 89/291 reads (31%) | called by muse, mutect2, varscan2
- BTNL8 | c.997T>G p.S333A | Missense Mutation (SNP) | VAF 80/89 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C11orf86 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C2CD4B | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CCT6B | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CD8A | c.292T>G p.F98V | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CDRT15 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- COL5A1 | c.638A>T p.D213V | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX29 | c.2000C>G p.S667C | Missense Mutation (SNP) | VAF 125/358 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ESR2 | c.764T>A p.V255E | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT tolerated (0.3); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FANCD2 | c.1718T>G p.I573S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- FAT3 | c.1947dup p.A650Cfs*8 | Frame Shift Ins (INS) | VAF 137/280 reads (49%) | called by pindel, varscan2
- FBN2 | c.4735T>G p.C1579G | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GALNT2 | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GAS2L2 | c.1406del p.G469Afs*32 | Frame Shift Del (DEL) | VAF 71/185 reads (38%) | called by mutect2, pindel, varscan2
- GPX3 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- GTF2I | c.859G>C p.E287Q (on ENST00000573035 / NM_032999.4; = p.E267Q on NM_001518.5) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- GUCY2D | c.696G>C p.K232N | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IGFBP5 | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- IGHV1-3 | c.28T>G p.L10V | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- IGLV4-3 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 136/375 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ILF3 | c.1111A>C p.K371Q | Missense Mutation (SNP) | VAF 155/524 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KNL1 | c.1228C>T p.H410Y (on ENST00000346991 / NM_170589.5; = p.H384Y on NM_144508.5) | Missense Mutation (SNP) | VAF 279/918 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRBA2 | c.1078T>A p.S360T | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KRT40 | c.361A>T p.I121F | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KRTAP10-9 | c.481T>A p.S161T | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- LRRK2 | c.2035del p.M679Cfs*14 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- MRC1 | c.2504T>C p.L835P | Missense Mutation (SNP) | VAF 146/443 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MTCH1 | c.1124T>A p.L375Q (on ENST00000373627 / NM_001271641.1; = p.L358Q on NM_014341.2) | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MTRR | c.1769A>C p.Q590P (on ENST00000264668; = p.Q563P on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/209 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NCOA3 | c.2033T>A p.L678* | Nonsense Mutation (SNP) | VAF 82/176 reads (47%) | called by muse, mutect2, varscan2
- OR5AP2 | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBPL11 | c.804A>T p.L268F | Missense Mutation (SNP) | VAF 78/289 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PCDH12 | c.2312A>T p.Q771L | Missense Mutation (SNP) | VAF 121/416 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PDS5B | c.2702del p.L901* | Frame Shift Del (DEL) | VAF 62/92 reads (67%) | called by mutect2, pindel, varscan2
- PKD1L3 | c.586-2A>G p.X196_splice | Splice Site (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- QSER1 | c.4601C>T p.P1534L (on ENST00000399302; = p.P1663L on NM_001076786.3) | Missense Mutation (SNP) | VAF 118/347 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM27 | c.1446T>A p.D482E | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- REPS1 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RIOX1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RREB1 | c.1952T>G p.V651G | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SALL3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SASH1 | c.936G>C p.K312N | Missense Mutation (SNP) | VAF 164/384 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SLC2A13 | c.212A>C p.Q71P | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC6A1 | c.1582G>A p.V528I | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TEX13C | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 129/143 reads (90%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TGDS | c.862dup p.W288Lfs*3 | Frame Shift Ins (INS) | VAF 19/29 reads (66%) | called by mutect2, pindel, varscan2
- TMC1 | c.864C>A p.S288R | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM225B | c.-4T>G | Splice Region (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2
- UTRN | c.3672G>C p.K1224N | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13C | c.6161T>C p.V2054A (on ENST00000644861 / NM_020821.3; = p.V2011A on NM_017684.5) | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- WDR19 | c.3834T>G p.I1278M | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XBP1 | c.241dup p.R81Kfs*17 | Frame Shift Ins (INS) | VAF 89/372 reads (24%) | called by mutect2, pindel, varscan2
- ZNF292 | c.5999C>A p.S2000* | Nonsense Mutation (SNP) | VAF 72/203 reads (35%) | called by muse, mutect2, varscan2
- ZNF384 | c.1339T>A p.Y447N (on ENST00000361959; = p.Y386N on NM_133476.5) | Missense Mutation (SNP) | VAF 163/332 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF418 | c.1452T>G p.C484W | Missense Mutation (SNP) | VAF 121/346 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ZPBP | c.716_717del p.L239Rfs*3 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- ZZEF1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ARHGAP31 | c.2529C>T p.H843= | Silent (SNP) | VAF 70/227 reads (31%) | called by muse, mutect2, varscan2
- ATP8B2 | c.2919T>C p.Y973= (on ENST00000672630; = p.Y940= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- C6orf118 | c.1096C>T p.L366= | Silent (SNP) | VAF 70/166 reads (42%) | called by muse, mutect2
- IGLL5 | c.81G>A p.L27= | Silent (SNP) | VAF 55/151 reads (36%) | catalogued as rs56055217, COSV73249379; called by muse, mutect2, varscan2
- KCNU1 | c.30T>C p.T10= | Silent (SNP) | VAF 129/287 reads (45%) | catalogued as rs748647937; called by muse, mutect2, varscan2
- MEI1 | c.954A>C p.S318= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs770536781; called by muse, mutect2, varscan2
- MLLT3 | c.1672C>T p.L558= | Silent (SNP) | VAF 113/226 reads (50%) | called by muse, mutect2, varscan2
- MYPOP | c.951G>A p.P317= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs780790539; called by muse, varscan2
- NOTUM | c.525A>G p.A175= | Silent (SNP) | VAF 126/283 reads (45%) | called by muse, mutect2, varscan2
- NUDT5 | c.87C>A p.V29= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV66718330; called by muse, mutect2, varscan2
- NXPE1 | c.259A>C p.R87= | Silent (SNP) | VAF 133/473 reads (28%) | called by muse, mutect2, varscan2
- REEP6 | c.192G>T p.V64= | Silent (SNP) | VAF 119/390 reads (31%) | called by muse, mutect2, varscan2
- RNF40 | c.273C>T p.L91= | Silent (SNP) | VAF 129/270 reads (48%) | catalogued as rs745374903; called by muse, mutect2, varscan2
- ROR2 | c.2385C>T p.P795= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs781565044; called by muse, mutect2, varscan2
- SFI1 | c.1353A>T p.A451= (on ENST00000400288 / NM_001007467.3; = p.A420= on NM_014775.4) | Silent (SNP) | VAF 58/197 reads (29%) | catalogued as COSV66290830; called by muse, mutect2, varscan2
- TBATA | c.72G>A p.K24= | Silent (SNP) | VAF 99/332 reads (30%) | called by muse, mutect2, varscan2
- TMEM245 | c.504C>T p.Y168= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- TRIM64B | c.450T>C p.N150= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- TRMO | c.633C>G p.P211= | Silent (SNP) | VAF 73/155 reads (47%) | catalogued as COSV100908860; called by muse, mutect2, varscan2
- AC020633.1 | n.2021T>C | RNA (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- ADAM12 | c.*1850T>A | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.*1171T>A | 3'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- ARPP19P2 | n.303G>C | RNA (SNP) | VAF 113/255 reads (44%) | called by muse, mutect2, varscan2
- ASPA | c.*3421A>G | 3'UTR (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- BTBD3 | c.*2256A>C | 3'UTR (SNP) | VAF 40/46 reads (87%) | called by muse, mutect2, varscan2
- CACNA1B | c.*794C>A | 3'UTR (SNP) | VAF 78/200 reads (39%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.632+45A>C | Intron (SNP) | VAF 53/128 reads (41%) | called by muse, mutect2, varscan2
- CAND1 | c.*2191T>G | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- CCDC39 | c.2266-450T>A | Intron (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- CD55 | c.980-45A>C | Intron (SNP) | VAF 128/272 reads (47%) | called by muse, mutect2
- CDCA3 | chr12:6845224 A>G | 3'Flank (SNP) | VAF 95/360 reads (26%) | called by muse, mutect2, varscan2
- CDH19 | c.*2640T>G | 3'UTR (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- CFAP92 | c.*1622G>A | 3'UTR (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- CHML | c.*1644A>G | 3'UTR (SNP) | VAF 62/137 reads (45%) | called by muse, mutect2, varscan2
- CHRM3 | c.*193A>C | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by mutect2, varscan2
- COL6A3 | c.*741A>C | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- COX10-AS1 | chr17:14024763 G>C | 3'Flank (SNP) | VAF 24/78 reads (31%) | called by muse, varscan2
- CXCL3 | c.309-38C>G | Intron (SNP) | VAF 55/178 reads (31%) | catalogued as COSV56017626; called by muse, mutect2, varscan2
- CXorf56 | c.*8T>C | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- DENND6A | c.*1760T>G | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- EFNB3 | c.*483T>C | 3'UTR (SNP) | VAF 16/405 reads (4%) | called by muse, mutect2
- ESM1 | c.*1055T>A | 3'UTR (SNP) | VAF 49/157 reads (31%) | called by muse, mutect2, varscan2
- FAM199X | c.*223C>G | 3'UTR (SNP) | VAF 29/35 reads (83%) | called by muse, mutect2, varscan2
- FGF5 | c.*1321A>G | 3'UTR (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- FOXJ2 | c.*2240C>T | 3'UTR (SNP) | VAF 58/120 reads (48%) | called by muse, mutect2, varscan2
- FSD1L | c.*4785A>T | 3'UTR (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- FZD6 | c.*51G>A | 3'UTR (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- GADL1 | c.1250+201G>T | Intron (SNP) | VAF 57/162 reads (35%) | called by muse, mutect2, varscan2
- GRIA4 | c.2295-5919G>A | Intron (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- HIC1 | c.37+143C>A | Intron (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- HS6ST2 | c.948-40065A>C | Intron (SNP) | VAF 20/63 reads (32%) | catalogued as COSV63717477; called by muse, mutect2, varscan2
- JPH3 | c.2167-881G>A | Intron (SNP) | VAF 100/210 reads (48%) | catalogued as rs1332011278; called by muse, mutect2, varscan2
- KCNT1 | chr9:135792994 G>A | 3'Flank (SNP) | VAF 96/181 reads (53%) | called by muse, mutect2, varscan2
- LMOD3 | c.*757C>A | 3'UTR (SNP) | VAF 47/161 reads (29%) | called by muse, mutect2, varscan2
- LRATD1 | c.-4A>T | 5'UTR (SNP) | VAF 66/168 reads (39%) | called by muse, mutect2, varscan2
- LRRC34 | c.-307C>T | 5'UTR (SNP) | VAF 53/158 reads (34%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-8521T>G | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- MBP | c.576+3020G>T | Intron (SNP) | VAF 61/224 reads (27%) | called by muse, mutect2, varscan2
- MCM10 | chr10:13210679 C>T | 3'Flank (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
- NHLRC2 | c.*5104T>A | 3'UTR (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- NOP56P1 | n.197C>G | RNA (SNP) | VAF 36/165 reads (22%) | catalogued as rs1475530153; called by muse, mutect2, varscan2
- ODF1 | c.-124A>T | 5'UTR (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*7739G>A | 3'UTR (SNP) | VAF 51/167 reads (31%) | called by muse, mutect2, varscan2
- OR4C7P | n.911C>G | RNA (SNP) | VAF 64/198 reads (32%) | called by muse, mutect2, varscan2
- PAICS | chr4:56435747 G>C | 5'Flank (SNP) | VAF 47/168 reads (28%) | called by muse, mutect2, varscan2
- PAQR9 | chr3:142950084 T>C | 3'Flank (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- PCMTD1 | c.-41T>G | 5'UTR (SNP) | VAF 33/316 reads (10%) | called by muse, mutect2, varscan2
- PFKP | chr10:3137584 G>A | 3'Flank (SNP) | VAF 117/359 reads (33%) | catalogued as rs772707878; called by muse, mutect2, varscan2
- PTBP1 | c.1075+20T>C | Intron (SNP) | VAF 104/336 reads (31%) | called by muse, mutect2, varscan2
- RAD18 | c.*3063A>T | 3'UTR (SNP) | VAF 38/108 reads (35%) | called by muse, mutect2, varscan2
- RELA | c.1033+155T>A | Intron (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- RPE | c.*1520T>A | 3'UTR (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- RTL6 | c.*2724G>T | 3'UTR (SNP) | VAF 43/164 reads (26%) | called by muse, mutect2
- SASH1 | c.*1809G>A | 3'UTR (SNP) | VAF 35/85 reads (41%) | catalogued as rs779630641; called by muse, mutect2, varscan2
- SCARB2 | c.-225C>T | 5'UTR (SNP) | VAF 23/74 reads (31%) | catalogued as rs1423574478; called by muse, mutect2, varscan2
- SDR16C5 | c.*176A>C | 3'UTR (SNP) | VAF 70/165 reads (42%) | called by muse, mutect2, varscan2
- SEC62 | c.*1538A>T | 3'UTR (SNP) | VAF 41/120 reads (34%) | called by muse, mutect2, varscan2
- SEPTIN10 | c.*1348G>A | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2
- SETBP1 | c.*1598C>T | 3'UTR (SNP) | VAF 38/249 reads (15%) | called by muse, mutect2, varscan2
- SGK1 | c.*333G>A | 3'UTR (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.*343C>A | 3'UTR (SNP) | VAF 45/49 reads (92%) | called by muse, mutect2, varscan2
- SLC35F2 | c.*1217G>T | 3'UTR (SNP) | VAF 66/235 reads (28%) | called by muse, mutect2, varscan2
- SPRYD4 | c.*3304T>A | 3'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57665903; called by mutect2, varscan2
- STEAP4 | c.*3398T>C | 3'UTR (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- STK32A | c.-27A>G | 5'UTR (SNP) | VAF 174/574 reads (30%) | called by muse, mutect2, varscan2
- SYNPO | c.*586G>T | 3'UTR (SNP) | VAF 161/513 reads (31%) | catalogued as rs920300891, COSV100302151, COSV56942124; called by muse, mutect2, varscan2
- TCAF2 | c.*1860T>C | 3'UTR (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- TIMP2 | c.*1405G>T | 3'UTR (SNP) | VAF 64/125 reads (51%) | called by muse, mutect2, varscan2
- TLE5 | c.190-55C>T | Intron (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- TNRC6B | c.5114+146A>G | Intron (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- TSPAN18 | c.-10-8618C>T | Intron (SNP) | VAF 207/746 reads (28%) | catalogued as rs748671757; called by muse, mutect2, varscan2
- TTC22 | c.*1270C>G | 3'UTR (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- TTPAL | c.*4078A>G | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- UBE2D3 | c.24+633C>G | Intron (SNP) | VAF 182/537 reads (34%) | called by muse, mutect2, varscan2
- UNC80 | c.-30C>A | 5'UTR (SNP) | VAF 42/74 reads (57%) | called by muse, varscan2
- VCAN | c.*1586T>G | 3'UTR (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- WDR47 | c.*190T>C | 3'UTR (SNP) | VAF 82/96 reads (85%) | called by muse, mutect2, varscan2
- WDR86 | chr7:151412825 G>A | 5'Flank (SNP) | VAF 111/313 reads (35%) | called by muse, mutect2, varscan2
- WHRN | c.1166+58T>A | Intron (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- WSCD2 | c.*12A>C | 3'UTR (SNP) | VAF 162/242 reads (67%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.*1609T>G | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- ZNF496 | c.651+435A>T | Intron (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- ZNF740 | c.-157C>T | 5'UTR (SNP) | VAF 22/241 reads (9%) | catalogued as COSV99914878; called by muse, mutect2
